Somatic mutation profile of tumor specimen TARGET-30-PAPCTS-01A (aliquot TARGET-30-PAPCTS-01A-01D) from TARGET case TARGET-30-PAPCTS, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.5 years (2,008 days).
Specimen TARGET-30-PAPCTS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c1b6bac-7dc5-4158-92e2-c7ea8995450e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPCTS-10A (Blood Derived Normal), aliquot TARGET-30-PAPCTS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74cdfe81-2742-4a14-be7a-10c905fa4f76

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE | c.2717C>A p.T906N | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV52013192; called by muse, mutect2, varscan2
- ADCY10 | c.2496T>A p.C832* | Nonsense Mutation (SNP) | VAF 66/181 reads (36%) | catalogued as COSV63241997, COSV63244989; called by muse, mutect2, varscan2
- CABIN1 | c.4273G>A p.D1425N | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV54089313; called by muse, mutect2, varscan2
- MLANA | c.202T>C p.C68R | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs370126913; called by muse, mutect2, varscan2
- MUC16 | c.41085A>C p.E13695D | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.878); catalogued as COSV66696672; called by muse, mutect2, varscan2
- PWWP3B | c.1474T>A p.Y492N | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61801769; called by muse, mutect2, varscan2
- SPEG | c.4355G>T p.C1452F | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.039); catalogued as COSV56679907; called by muse, mutect2, varscan2
- ACSM5 | c.1592_1600dup p.T533_R534insPLT | In Frame Ins (INS) | VAF 40/158 reads (25%) | called by mutect2, varscan2
- FRMPD1 | c.3339C>T p.D1113= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV66703195; called by muse, mutect2, varscan2
- ITGA2B | c.1242C>T p.P414= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV52235230; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851858 A>G | 3'Flank (SNP) | VAF 67/78 reads (86%) | called by muse, mutect2, varscan2
